CCDI case PBBNJH — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/d51544ec-171d-479d-854d-2dc92166e4b9

Demographics
Sex at birth: male; Race: white; Vital status: Alive.

Diagnoses (1)
1. Pilocytic astrocytoma: ICD-O-3 morphology code: 9421/1; Tissue or organ of origin: Temporal lobe; Age at diagnosis: 9.0 years (3,278 days).

Biospecimens (3 samples)
- Sample 0DDKE2: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DDKEQ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DDKER: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
